Gene-level copy-number profile of tumor specimen TCGA-RS-A6TP-01A from TCGA case TCGA-RS-A6TP, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 58.6 years (21,393 days).
Specimen TCGA-RS-A6TP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e8417e27-1a53-49c2-8e0d-bd0f3ff8a1b5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RS-A6TP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cd0715d5-6a4a-4d40-823b-295e23ff01e7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,444; copy number 2: 51,478; copy number 3: 266; copy number 4: 1,429; copy number 5: 7; copy number 6: 77; copy number 12: 114.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RS-A6TP-01A-12D-A34I-01): tumor purity 0.88, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 198 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:31,257,664–36,270,918, 198 genes, copy number 5–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,063. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
